Somatic mutation profile of tumor specimen 0DRO3W from CCDI case PBCGEB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 14.9 years (5,452 days).
Specimen 0DRO3W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efd484b9-d049-467f-839b-ed6178a72036.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRO3J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c380e36-879d-408e-957e-5a6916ca0a17

The open-access MAF lists 45 somatic variants for this specimen: 30 protein-altering or splice-affecting, 5 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 5, Intron 4, Nonsense Mutation 3, RNA 3, Splice Region 3, 3'UTR 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>T p.R479L (on ENST00000281708 / NM_001349798.2; = p.R399L on NM_018315.5) | Missense Mutation (SNP) | VAF 196/554 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by mutect2, varscan2
- ABL2 | c.2018G>A p.R673Q (on ENST00000502732 / NM_007314.4; = p.R658Q on NM_005158.5) | Missense Mutation (SNP) | VAF 89/240 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs1424546413; called by muse, mutect2, varscan2
- B3GAT1 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 148/615 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as rs367583989, COSV100437896; called by muse, mutect2, varscan2
- BCOR | c.4450G>T p.E1484* (on ENST00000378444 / NM_001123385.2; = p.E1450* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 257/325 reads (79%) | catalogued as COSV60701158; called by muse, mutect2, varscan2
- CAPN9 | c.1825G>A p.G609S | Missense Mutation (SNP) | VAF 194/955 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769880929, COSV99680173; called by muse, mutect2, varscan2
- CCDC144A | c.1216G>T p.D406Y | Missense Mutation (SNP) | VAF 445/1196 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV60700753; called by muse, mutect2, varscan2
- LIMCH1 | c.2444G>A p.R815H | Missense Mutation (SNP) | VAF 168/430 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776885660, COSV104402953; called by muse, mutect2, varscan2
- LRRC8B | c.2172C>A p.C724* | Nonsense Mutation (SNP) | VAF 198/547 reads (36%) | catalogued as COSV99044090; called by muse, mutect2, varscan2
- MSMO1 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 383/1059 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs754262741; called by muse, mutect2, varscan2
- MYO1F | c.414+7C>T | Splice Region (SNP) | VAF 79/229 reads (34%) | catalogued as rs200488055; called by muse, mutect2, varscan2
- OR10K1 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 173/485 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV56875299; called by mutect2, varscan2
- PRAMEF1 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 64/554 reads (12%) | catalogued as COSV60009393; called by mutect2, varscan2
- REG1A | c.191G>T p.C64F | Missense Mutation (SNP) | VAF 356/1345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52071705; called by muse, mutect2, varscan2
- STK11 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 145/607 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as rs398123405, COSV58821297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEPP | c.551C>A p.T184K | Missense Mutation (SNP) | VAF 149/363 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV52044125; called by muse, mutect2, varscan2
- ZBP1 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 151/346 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs754610408, COSV100474089; called by muse, mutect2, varscan2
- ATP7B | c.2330G>A p.G777D | Missense Mutation (SNP) | VAF 317/1251 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNGA4 | c.1507C>A p.Q503K | Missense Mutation (SNP) | VAF 223/842 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND1A | c.1645C>A p.Q549K | Missense Mutation (SNP) | VAF 122/393 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- FCGBP | c.6634G>A p.G2212R | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FHAD1 | c.1863G>T p.Q621H | Missense Mutation (SNP) | VAF 193/543 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCA | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 282/1180 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- IVL | c.874C>A p.Q292K | Missense Mutation (SNP) | VAF 113/299 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- LILRB4 | c.1231G>T p.V411L (on ENST00000391733 / NM_001278428.3; = p.V410L on NM_001278426.3) | Missense Mutation (SNP) | VAF 124/552 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- PACS2 | c.1614-3C>A | Splice Region (SNP) | VAF 92/240 reads (38%) | called by muse, mutect2, varscan2
- PLCL2 | c.2032A>G p.S678G (on ENST00000615277 / NM_001144382.2; = p.S552G on NM_015184.5) | Missense Mutation (SNP) | VAF 145/792 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- PRPH | c.703-4G>A | Splice Region (SNP) | VAF 157/556 reads (28%) | called by muse, mutect2, varscan2
- PTPN13 | c.2375G>T p.G792V | Missense Mutation (SNP) | VAF 322/785 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- THPO | c.796C>A p.Q266K (on ENST00000649095 / NM_001290003.1; = p.Q126K on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 194/560 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- XRN1 | c.1193G>T p.C398F | Missense Mutation (SNP) | VAF 314/791 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- BDKRB2 | c.732G>T p.T244= | Silent (SNP) | VAF 230/589 reads (39%) | called by muse, mutect2, varscan2
- PPM1K | c.468G>A p.L156= | Silent (SNP) | VAF 46/1332 reads (3%) | called by muse, mutect2
- PRKAB1 | c.786C>T p.V262= | Silent (SNP) | VAF 164/807 reads (20%) | catalogued as rs1259042050, COSV57555183; called by muse, mutect2, varscan2
- TLE5 | c.483C>T p.T161= | Silent (SNP) | VAF 93/345 reads (27%) | catalogued as rs1169377814; called by muse, mutect2, varscan2
- ZNF225 | c.408A>G p.A136= | Silent (SNP) | VAF 232/929 reads (25%) | called by muse, mutect2, varscan2
- AC114316.1 | n.1694C>T | RNA (SNP) | VAF 123/352 reads (35%) | called by muse, mutect2, varscan2
- CCDC74B | c.295+66G>T | Intron (SNP) | VAF 86/345 reads (25%) | called by muse, mutect2, varscan2
- CCDC92B | n.144G>T | RNA (SNP) | VAF 128/390 reads (33%) | called by muse, mutect2, varscan2
- CLEC19A | chr16:19307653 C>A | 3'Flank (SNP) | VAF 124/349 reads (36%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.86-6547C>A | Intron (SNP) | VAF 254/799 reads (32%) | called by muse, mutect2, varscan2
- CXCL2 | c.100+18G>A | Intron (SNP) | VAF 108/316 reads (34%) | called by muse, mutect2, varscan2
- FCAR | c.*17G>C | 3'UTR (SNP) | VAF 80/304 reads (26%) | called by muse, mutect2, varscan2
- LINC01811 | n.294C>A | RNA (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- TMEM104 | c.*56C>T | 3'UTR (SNP) | VAF 26/87 reads (30%) | catalogued as rs1402179266; called by muse, mutect2, varscan2
- TTLL3 | c.1548-86C>A | Intron (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
